Gene-level copy-number profile of tumor specimen TCGA-24-1604-01A from TCGA case TCGA-24-1604, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 67.0 years (24,471 days).
Specimen TCGA-24-1604-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.644ce6b1-1823-4eb8-bc5d-029b3f51fe2f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-1604-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1ac117c4-7d99-490c-99a6-a15239ae18cc

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,621; copy number 2: 15,149; copy number 3: 19,711; copy number 4: 12,870; copy number 5: 2,932; copy number 6: 4,352; copy number 7: 1,212; copy number 8: 1,183; copy number 9: 694; copy number 10: 96.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-24-1604-01): tumor purity 0.82, ploidy 3.37, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,185 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:180,632,022–225,653,142, 791 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr6:9,596,110–29,431,967, 466 genes, copy number 8–10 (within-gene range 6–10) (broad region; genes not listed).
- chr7:135,246,113–137,354,483, 29 genes, copy number 7 (within-gene range 6–7): SLC23A4P, CNOT4, SDHDP2, NUP205, AC093107.2, AC093107.1, STMP1, RNU6-1154P, SLC13A4, AC091736.1, FAM180A, AC015987.1, MTPN, RNU6-223P, AC024084.1, AC078845.1, Y_RNA, AC009784.1, ZP3P2, AC009264.1, PSMC1P3, CHRM2, MIR490, KRT8P51, AC009517.1, PTN, SNORD81, AC078842.2, AC078842.1.
- chr8:40,530,590–47,736,306, 118 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr8:54,042,989–63,693,249, 148 genes, copy number 8–10 (broad region; genes not listed).
- chr8:63,703,077–63,813,937, 2 genes, copy number 9 (within-gene range 5–9): AC069133.1, LINC01289.
- chr8:113,950,886–145,066,685, 511 genes, copy number 9 (broad region; genes not listed).
- chr11:66,070,272–102,880,846, 846 genes, copy number 8 (within-gene range 5–8) (broad region; genes not listed).
- chr11:115,128,218–115,504,957, 6 genes, copy number 7: AP003179.1, CADM1, AP000465.1, AP000462.3, AP000462.1, AP000462.2.
- chr20:50,999,370–63,657,682, 268 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,621. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
